Somatic mutation profile of tumor specimen TARGET-30-PASPER-01A (aliquot TARGET-30-PASPER-01A-01D) from TARGET case TARGET-30-PASPER, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.1 years (753 days).
Specimen TARGET-30-PASPER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a9cada3-6dd8-4532-ad35-8cb97e83b401.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASPER-10A (Blood Derived Normal), aliquot TARGET-30-PASPER-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e1972f4-e6e8-4853-b92e-34d63e7e7319

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA2C | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57467626, COSV57467689; called by mutect2, varscan2
- CCDC153 | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV59540621; called by muse, mutect2, varscan2
- CDH12 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66419820; called by muse, mutect2, varscan2
- CLTCL1 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as COSV54233863, COSV54240478; called by muse, mutect2, varscan2
- CSPG4 | c.1966G>T p.V656L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs538165446, COSV57897656; called by mutect2, varscan2
- GRAMD1C | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1427126456, COSV63983189; called by muse, mutect2, varscan2
- INTS2 | c.3252G>T p.M1084I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.448); catalogued as rs751347886, COSV52154321; called by muse, mutect2, varscan2
- KCNQ3 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66465071, COSV66484854; called by muse, mutect2
- MDN1 | c.8175C>A p.D2725E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65524451; called by muse, mutect2, varscan2
- POLR2A | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59493634; called by muse, mutect2, varscan2
- RP1 | c.1458T>G p.S486R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV55120366; called by muse, mutect2, varscan2
- TNXB | c.11480A>T p.Q3827L (on ENST00000647633; = p.Q3580L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV64482448; called by muse, mutect2, varscan2
- ZBTB40 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs779123734, COSV65145771; called by muse, mutect2, varscan2
- ZNF630 | c.1943C>G p.P648R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.367); catalogued as COSV52097265, COSV99332583; called by muse, mutect2, varscan2
- ZNF682 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as rs1459841991, COSV62067734; called by muse, mutect2, varscan2
- NOTCH2 | c.7009C>A p.P2337T | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- DDR2 | c.336C>T p.I112= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs146276174; called by muse, mutect2, varscan2
- SELENBP1 | c.297C>A p.L99= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV64373708; called by muse, varscan2
- TUBA3D | c.690G>C p.L230= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV58312386; called by muse, mutect2, varscan2
- RUSC1 | c.-118C>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as COSV52740959; called by muse, mutect2, varscan2
- VAV3 | c.322-5985C>G | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
